Somatic mutation profile of tumor specimen C3N-05106-01 (aliquot CPT0438460009) from CPTAC case C3N-05106, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.1 years (26,320 days).
Specimen C3N-05106-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 206b9005-a008-4d98-8f57-11610e7e5c2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-05106-31 (Blood Derived Normal), aliquot CPT0444760003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52a226c0-172c-411c-a69c-949a9bc40aca

The open-access MAF lists 1,290 somatic variants for this specimen: 818 protein-altering or splice-affecting, 422 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 755, Silent 422, Nonsense Mutation 45, Intron 27, Splice Region 7, 3'UTR 6, 5'Flank 6, Splice Site 4, RNA 4, Frame Shift Del 4, 5'UTR 4, 3'Flank 3.

Variants (750 of 1,290; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs778673716, CM044879, CM994322; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.362G>C p.C121S | Missense Mutation (SNP) | VAF 78/400 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1057519731, COSV61069878; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 68/352 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 54/195 reads (28%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- PKHD1 | c.10444C>T p.R3482C | Missense Mutation (SNP) | VAF 68/458 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs148617572, CM032336; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- A2M | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV59383821; called by muse, varscan2
- AADACL2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780021458, COSV62930020; called by muse, mutect2, varscan2
- ABCA9 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 69/372 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV60624635; called by muse, mutect2, varscan2
- ABCC11 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 63/292 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs769540170; called by muse, mutect2, varscan2
- AC008397.1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1336990902; called by muse, mutect2, varscan2
- AC126283.2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773085612, CM161603, COSV67098504; called by muse, mutect2, varscan2
- ACMSD | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs757421443, COSV51607251; called by muse, varscan2
- ADAM2 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55860152; called by muse, mutect2, varscan2
- ADAMTS18 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 87/330 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867875220, COSV51406551; called by muse, mutect2, varscan2
- ADAMTS2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 63/417 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755997172, COSV51072403; called by muse, mutect2, varscan2
- ADAMTS6 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 73/332 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.363); catalogued as rs574046720, COSV58681823; called by muse, mutect2, varscan2
- ADAMTS7 | c.3253G>A p.D1085N | Missense Mutation (SNP) | VAF 80/421 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs538382275, COSV101183246; called by muse, mutect2, varscan2
- AGO3 | c.2449C>T p.H817Y | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.679); catalogued as COSV55795224; called by muse, mutect2, varscan2
- AKR1C1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1471636426, COSV101080393; called by muse, mutect2, varscan2
- AKR1C2 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1554773538, COSV101060363; called by muse, mutect2, varscan2
- AKR1D1 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54336573; called by muse, mutect2, varscan2
- ALPK3 | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 53/387 reads (14%) | catalogued as rs751041696; called by muse, mutect2, varscan2
- ANK1 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as COSV55879004; called by muse, mutect2, varscan2
- ANKH | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV52479248; called by muse, mutect2, varscan2
- ANKRD40 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 137/522 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs564401651; called by muse, mutect2, varscan2
- ANKRD61 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 84/421 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs759663168; called by muse, mutect2, varscan2
- AOC1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 86/407 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773370272; called by muse, mutect2, varscan2
- ARHGAP22 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 91/502 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs1406003309, COSV50933304; called by muse, mutect2, varscan2
- ARHGAP29 | c.2882G>A p.G961E | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867918256, COSV53110801; called by muse, mutect2, varscan2
- ARSF | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs1365580969; called by muse, mutect2, varscan2
- ATG9B | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs375373377; called by muse, mutect2, varscan2
- ATP13A4 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776106725, COSV55071508; called by muse, mutect2, varscan2
- BARHL1 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 87/480 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as COSV55037356; called by muse, mutect2, varscan2
- BAZ2B | c.5339G>A p.R1780Q | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.365); catalogued as rs370048337; called by muse, mutect2, varscan2
- BMPR2 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV65813612; called by muse, mutect2, varscan2
- BSN | c.10372G>A p.D3458N | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1377170357, COSV56520163; called by muse, mutect2, varscan2
- C1orf87 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 70/384 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs772529746, COSV64598000, COSV64599212; called by muse, mutect2, varscan2
- C20orf194 | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV52696794, COSV99330828; called by muse, mutect2, varscan2
- CBY2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 84/456 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as rs772453073, COSV60118333; called by muse, mutect2
- CCDC198 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs1433662513; called by muse, mutect2, varscan2
- CD163 | c.3137C>T p.S1046F | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV63138374; called by muse, mutect2, varscan2
- CD163 | c.1951C>T p.H651Y | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV63132174; called by muse, mutect2, varscan2
- CD163 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.841); catalogued as rs769304068; called by muse, mutect2, varscan2
- CDH18 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 86/369 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV56924251; called by muse, mutect2, varscan2
- CDH8 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 84/515 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100183823; called by muse, mutect2, varscan2
- CELA2A | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as rs141015619; called by muse, mutect2, varscan2
- CENPT | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 167/440 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV54649899; called by muse, mutect2, varscan2
- CES4A | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV100110301; called by muse, mutect2, varscan2
- CFAP57 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 92/447 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as rs1352408282; called by muse, mutect2, varscan2
- CFHR5 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1049224798, COSV56829221; called by muse, mutect2, varscan2
- CLEC14A | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 93/528 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60562180; called by muse, mutect2, varscan2
- CLEC16A | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 68/367 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55490069; called by muse, mutect2, varscan2
- CLEC4C | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV63582567; called by muse, mutect2, varscan2
- COL12A1 | c.5659G>A p.E1887K | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as COSV59398955; called by muse, mutect2, varscan2
- COL12A1 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 76/448 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1233438359; called by muse, mutect2, varscan2
- COL18A1 | c.2288C>T p.P763L (on ENST00000359759 / NM_130444.3; = p.P528L on NM_030582.4) | Missense Mutation (SNP) | VAF 78/442 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs372859456; called by muse, varscan2
- COL18A1 | c.3266C>T p.A1089V (on ENST00000359759 / NM_130444.3; = p.A854V on NM_030582.4) | Missense Mutation (SNP) | VAF 87/447 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.616); catalogued as COSV60594335; called by muse, mutect2, varscan2
- COL25A1 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866556873; called by muse, mutect2, varscan2
- COL4A5 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60360828; called by muse, mutect2, varscan2
- COL4A5 | c.1668G>A p.M556I | Missense Mutation (SNP) | VAF 119/415 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1259096172; called by muse, mutect2, varscan2
- COL6A5 | c.4799G>A p.G1600E | Missense Mutation (SNP) | VAF 75/279 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1264819159; called by muse, mutect2, varscan2
- COL6A6 | c.2840G>A p.G947E | Missense Mutation (SNP) | VAF 86/453 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100649746, COSV62027245; called by muse, mutect2, varscan2
- COL6A6 | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 59/341 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1397172921, COSV62034700; called by muse, mutect2, varscan2
- COL9A1 | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 175/393 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100295051; called by muse, mutect2, varscan2
- CPA3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199600994, COSV56044010; called by muse, mutect2, varscan2
- CPXM2 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 87/426 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs769452613, COSV53859505; called by muse, mutect2, varscan2
- CR1 | c.5479C>T p.P1827S | Missense Mutation (SNP) | VAF 132/522 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as rs754871656; called by muse, mutect2, varscan2
- CRTAC1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 67/353 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.119); catalogued as rs1332163304; called by muse, mutect2, varscan2
- CSMD2 | c.6836G>A p.G2279E | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs773952980; called by muse, mutect2, varscan2
- CUX2 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 118/584 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as rs866261779, COSV55639655; called by muse, mutect2, varscan2
- CYP11B1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs762347776, COSV52825046; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- DACH2 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64170583; called by muse, mutect2, varscan2
- DAGLA | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 82/392 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV57195659; called by muse, mutect2, varscan2
- DCAF16 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as COSV66384244; called by muse, mutect2, varscan2
- DCAF8L2 | c.1400G>A p.R467K | Missense Mutation (SNP) | VAF 77/331 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV70550263; called by muse, mutect2, varscan2
- DDC | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769418481, COSV63566150; called by muse, mutect2, varscan2
- DKK2 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 51/359 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV99569665; called by muse, mutect2, varscan2
- DMBT1 | c.6271C>T p.L2091F (on ENST00000338354 / NM_001377530.1; = p.L1334F on NM_004406.3) | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1235818602; called by muse, mutect2, varscan2
- DMRTC1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1556350990; called by muse, mutect2, varscan2
- DMXL2 | c.8152C>T p.R2718C | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.387); catalogued as rs758537533, COSV51853206; called by muse, mutect2, varscan2
- DNAH11 | c.10036C>T p.R3346* | Nonsense Mutation (SNP) | VAF 54/282 reads (19%) | catalogued as rs773851007, COSV60970262; called by muse, mutect2, varscan2
- DNAH14 | c.5911G>A p.D1971N (on ENST00000445597; = p.D2511N on NM_001367479.1) | Missense Mutation (SNP) | VAF 69/406 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1295336302; called by muse, mutect2, varscan2
- DNAH14 | c.8821G>A p.E2941K (on ENST00000445597; = p.E3744K on NM_001367479.1) | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV104405605; called by muse, mutect2, varscan2
- DNAH17 | c.11869G>A p.G3957S | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as rs561827431; called by muse, mutect2, varscan2
- DNAH5 | c.7839G>A p.M2613I | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1486813109, COSV54201446; called by muse, mutect2, varscan2
- DNAH8 | c.11914G>A p.E3972K | Missense Mutation (SNP) | VAF 138/405 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as COSV59475841; called by muse, mutect2, varscan2
- DNAH9 | c.3827C>T p.S1276F | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV99307861; called by muse, mutect2, varscan2
- DNER | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs746572847; called by muse, mutect2, varscan2
- DOCK11 | c.2855dup p.L952Ffs*15 | Frame Shift Ins (INS) | VAF 44/222 reads (20%) | catalogued as rs749353751; called by pindel, varscan2
- DSCAM | c.4309C>T p.R1437C | Missense Mutation (SNP) | VAF 67/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757906374, COSV68028777; called by muse, mutect2, varscan2
- DSCAM | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1360887980, COSV68655329; called by muse, mutect2, varscan2
- DSCAML1 | c.4582G>A p.E1528K (on ENST00000321322; = p.E1468K on NM_020693.4) | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs752493281; called by muse, mutect2, varscan2
- DUOX2 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1436489952, COSV66533550; called by muse, mutect2, varscan2
- EHBP1 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1454079058, COSV99861868; called by muse, mutect2, varscan2
- ELFN2 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs777867053; called by muse, mutect2, varscan2
- ELL2 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs565698629; called by muse, mutect2
- ENAM | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs1191646719; called by muse, mutect2, varscan2
- EPHB2 | c.1856C>T p.S619F (on ENST00000400191 / NM_001309193.2; = p.S620F on NM_004442.7) | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1392948771; called by muse, mutect2, varscan2
- ERBB2 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 87/490 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs759579850; called by muse, varscan2
- ERCC4 | c.2264C>T p.P755L | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61311096; called by muse, mutect2, varscan2
- ESRP1 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64407649; called by muse, mutect2, varscan2
- ETAA1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs773523823; called by muse, mutect2, varscan2
- F7 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs531916165, CM1512318, COSV60646779; called by muse, mutect2, varscan2
- F8 | c.4246C>T p.P1416S | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV100812091; called by muse, varscan2
- F8 | c.4238C>T p.S1413L | Missense Mutation (SNP) | VAF 70/335 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as CD1212737, COSV64273624; called by muse, varscan2
- F8 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as CM153194; called by muse, mutect2, varscan2
- FAM107B | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 81/470 reads (17%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99474475; called by muse, mutect2, varscan2
- FAM186B | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs1009642039; called by muse, mutect2, varscan2
- FAM47A | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 82/358 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.135); catalogued as COSV100649799; called by muse, mutect2, varscan2
- FAM47C | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 128/484 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.321); catalogued as COSV63730787; called by muse, mutect2, varscan2
- FAM90A1 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 80/375 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs781068871; called by muse, mutect2, varscan2
- FAT1 | c.4013C>T p.T1338I | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.562); catalogued as COSV101498603, COSV71676490; called by muse, mutect2, varscan2
- FAT2 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 86/446 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1278222147; called by muse, mutect2, varscan2
- FBLN2 | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99852579; called by muse, mutect2, varscan2
- FCN2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs1413481250, COSV52477069; called by muse, mutect2, varscan2
- FCRL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs267598092, COSV63823853; called by muse, varscan2
- FGF18 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 70/305 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51128254; called by muse, mutect2, varscan2
- FGF23 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1286090989, COSV52976058; called by muse, mutect2, varscan2
- FGFR2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60647224; called by muse, mutect2, varscan2
- FLNB | c.7460C>T p.S2487F | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs771879974, COSV99913790; called by muse, mutect2, varscan2
- FOXP2 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV63485484; called by muse, mutect2, varscan2
- FREM1 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs866797834; called by muse, mutect2, varscan2
- FSTL5 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.142); catalogued as rs182769441, COSV100059184; called by muse, mutect2, varscan2
- GALNT14 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs765821121, COSV61106650, COSV61106942; called by muse, mutect2, varscan2
- GALNT16 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 76/410 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61885617; called by muse, varscan2
- GIMAP1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 92/484 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV56187458; called by muse, varscan2
- GJA8 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782429592, COSV53790475; called by muse, mutect2, varscan2
- GLI2 | c.1615C>T p.R539C (on ENST00000361492 / NM_001374353.1; = p.R556C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58034512, COSV58039499; called by muse, mutect2, varscan2
- GLYATL3 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 111/302 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1297519497; called by muse, mutect2, varscan2
- GML | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs1276968506, COSV55278508, COSV55278610; called by muse, mutect2, varscan2
- GML | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV55278268, COSV55278556; called by muse, mutect2, varscan2
- GOLGA6C | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); catalogued as rs1344487467; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1973G>A p.R658K | Missense Mutation (SNP) | VAF 108/716 reads (15%) | SIFT tolerated, low confidence (0.72); catalogued as rs1379426125, COSV61481455; called by muse, mutect2, varscan2
- GON4L | c.3331C>T p.R1111* | Nonsense Mutation (SNP) | VAF 159/440 reads (36%) | catalogued as COSV55195341; called by muse, mutect2, varscan2
- GPC6 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 75/388 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.532); catalogued as COSV65516351; called by muse, mutect2, varscan2
- GPR4 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 67/406 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as rs773744239, COSV59917449; called by muse, mutect2, varscan2
- GRIA1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs780461979, COSV53617450, COSV53629433; called by muse, mutect2, varscan2
- GRIA4 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV56919688; called by muse, mutect2, varscan2
- GRIN2B | c.3544G>A p.G1182R | Missense Mutation (SNP) | VAF 84/406 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.131); catalogued as rs1248498963; called by muse, varscan2
- GRIP2 | c.3007C>T p.L1003F (on ENST00000619221; = p.L906F on NM_001080423.4) | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.73); catalogued as rs775395395, COSV56119881; called by muse, mutect2, varscan2
- GYPA | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV51636726; called by muse, mutect2, varscan2
- HFM1 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54025957, COSV54037589; called by muse, mutect2, varscan2
- HHLA2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 88/400 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as rs367817011, COSV63316232; called by muse, mutect2, varscan2
- HNRNPA1P48 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.296); catalogued as rs547650794; called by muse, mutect2, varscan2
- HRNR | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 175/591 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs367548706; called by muse, mutect2, varscan2
- HS6ST2 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as rs762429850, COSV63710808; ClinVar: uncertain significance; called by muse, varscan2
- HTR1A | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60503372; called by muse, mutect2, varscan2
- HYAL4 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 75/384 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs778623342, COSV56137678; called by muse, mutect2, varscan2
- IBSP | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs748954490, COSV56894710, COSV56896288; called by muse, mutect2, varscan2
- IGHG4 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 104/665 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.12); catalogued as rs587772292; called by muse, mutect2, varscan2
- IGHV3-21 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as rs781812637; called by muse, varscan2
- IL21R | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 70/626 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767388017, COSV61969748; called by muse, varscan2
- IL37 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs145730208, COSV54492103; called by muse, mutect2, varscan2
- IL7 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.409); catalogued as COSV55676026; called by muse, mutect2, varscan2
- IPP | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs775387137, COSV63432633; called by muse, mutect2, varscan2
- IQGAP2 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 77/403 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV57173046; called by muse, mutect2, varscan2
- ITGA11 | c.374G>A p.W125* | Nonsense Mutation (SNP) | VAF 34/232 reads (15%) | catalogued as rs1283465792; called by muse, mutect2, varscan2
- ITGA8 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 80/467 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV65228633; called by muse, mutect2, varscan2
- ITGB8 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.967); catalogued as COSV56011827; called by muse, mutect2, varscan2
- ITPKB | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 151/488 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs751661834; called by muse, mutect2, varscan2
- JAKMIP1 | c.1506C>A p.Y502* | Nonsense Mutation (SNP) | VAF 84/452 reads (19%) | catalogued as COSV51523247; called by muse, mutect2, varscan2
- KAT6A | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); catalogued as COSV55906962; called by muse, mutect2, varscan2
- KCNJ12 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 73/599 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1179558149; called by muse, mutect2, varscan2
- KIAA1109 | c.8740C>T p.R2914* | Nonsense Mutation (SNP) | VAF 59/281 reads (21%) | catalogued as COSV52698099; called by muse, mutect2, varscan2
- KIF6 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs757595486; called by muse, mutect2, varscan2
- KLHL13 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs182356687, COSV53244944; called by muse, mutect2, varscan2
- KRT75 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 67/393 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781361449, COSV52875452; called by muse, mutect2, varscan2
- L1CAM | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV100649576; called by muse, mutect2, varscan2
- LAMB1 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs532611294; called by muse, mutect2, varscan2
- LIG4 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV63598172; called by muse, mutect2, varscan2
- LILRA2 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 100/574 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs1247709590, COSV52195220; called by muse, varscan2
- LINGO2 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs780715183, COSV58058037, COSV58061817; called by muse, mutect2, varscan2
- LMNTD2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 85/435 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750490846; called by muse, mutect2, varscan2
- LRP2 | c.12137G>A p.R4046Q | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as rs867978150; called by muse, mutect2, varscan2
- LRRC3B | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV101185747, COSV67520069; called by muse, mutect2, varscan2
- LRRC4C | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 92/457 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53427377; called by muse, mutect2, varscan2
- LRRC55 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 77/384 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV73006536; called by muse, mutect2, varscan2
- LRRC7 | c.724G>A p.D242N (on ENST00000651989 / NM_001370785.2; = p.D209N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as COSV99224658; called by muse, mutect2, varscan2
- LRRTM4 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 78/418 reads (19%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.06); catalogued as COSV69153795; called by muse, varscan2
- MAB21L4 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.025); catalogued as rs1003651122, COSV100278522; called by muse, mutect2, varscan2
- MAGEB1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 91/403 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV66775620; called by muse, mutect2, varscan2
- MAGEE1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 71/336 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373804803, COSV63909530; called by muse, mutect2, varscan2
- MAGIX | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 98/434 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs1557098018; called by muse, mutect2, varscan2
- MAP4K1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50263901; called by muse, mutect2, varscan2
- MAST4 | c.7690G>A p.D2564N (on ENST00000403625 / NM_001164664.2; = p.D2375N on NM_015183.3) | Missense Mutation (SNP) | VAF 110/463 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV99845823; called by muse, mutect2, varscan2
- MCM7 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as rs866091810; called by muse, mutect2, varscan2
- MDN1 | c.12592C>T p.R4198C | Missense Mutation (SNP) | VAF 60/345 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs757305972; called by muse, mutect2, varscan2
- ME1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868866711, COSV63839544; called by muse, varscan2
- MECOM | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs866865800; called by muse, varscan2
- MECOM | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 78/364 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761171278, COSV72110504; called by muse, varscan2
- MEIOC | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 107/450 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV63440603; called by muse, mutect2, varscan2
- MEIS1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 86/375 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.194); catalogued as COSV55489580; called by muse, mutect2, varscan2
- MICALL1 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 92/381 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs1287494179; called by muse, mutect2, varscan2
- MKLN1 | c.2005C>T p.H669Y | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61759959; called by muse, mutect2, varscan2
- MME | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 50/338 reads (15%) | catalogued as COSV64706102; called by muse, mutect2, varscan2
- MORC2 | c.317C>T p.S106L (on ENST00000397641 / NM_001303256.3; = p.S44L on NM_014941.3) | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53201035; called by muse, mutect2, varscan2
- MOXD1 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV60944233; called by muse, mutect2, varscan2
- MPO | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759936739; called by muse, mutect2, varscan2
- MRGPRX1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs867594179, COSV57105773; called by muse, varscan2
- MROH2B | c.2330C>T p.S777F | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV68181333; called by muse, mutect2, varscan2
- MROH2B | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1451889213, COSV101270575, COSV101270679; called by muse, mutect2, varscan2
- MROH7 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1352054394, COSV100273799, COSV59868065; called by muse, mutect2, varscan2
- MS4A12 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs889178913, COSV50014281; called by muse, mutect2, varscan2
- MUC16 | c.22906C>T p.L7636F | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.221); catalogued as COSV101199274; called by muse, mutect2, varscan2
- MUC16 | c.10559C>T p.S3520L | Missense Mutation (SNP) | VAF 75/331 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV67449114; called by muse, mutect2, varscan2
- MUC16 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs763691043, COSV67448892; called by muse, mutect2, varscan2
- MUC4 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 139/717 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs1013696488; called by muse, mutect2, varscan2
- MUC5B | c.15688G>A p.D5230N | Missense Mutation (SNP) | VAF 92/350 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.46); catalogued as COSV71594284; called by muse, mutect2, varscan2
- MYCBP2 | c.851C>T p.S284L (on ENST00000357337; = p.S322L on NM_015057.5) | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs376931021; called by muse, mutect2, varscan2
- MYH10 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs727504231, CM1410657, COSV104369093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH13 | c.4078G>A p.E1360K | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs371382799, COSV52822284; called by muse, mutect2, varscan2
- MYH4 | c.2588C>T p.T863I | Missense Mutation (SNP) | VAF 74/375 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs766143426, COSV55127608; called by muse, mutect2, varscan2
- MYH4 | c.1851G>A p.M617I | Missense Mutation (SNP) | VAF 86/414 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55126526; called by muse, mutect2, varscan2
- MYOF | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs750361835; called by muse, mutect2, varscan2
- MYOM2 | c.4327C>T p.P1443S | Missense Mutation (SNP) | VAF 120/564 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs920809750; called by muse, mutect2, varscan2
- N4BP2 | c.4366C>T p.P1456S | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs267600152; called by muse, mutect2, varscan2
- NAALADL2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV70795326; called by muse, mutect2, varscan2
- NCOA1 | c.3698C>T p.P1233L | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs1357021921; called by muse, mutect2, varscan2
- NDUFB8 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs767181095; called by muse, mutect2, varscan2
- NF1 | c.5536C>T p.R1846W (on ENST00000358273 / NM_001042492.3; = p.R1825W on NM_000267.3) | Missense Mutation (SNP) | VAF 70/335 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs769843989, COSV99049826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIPBL | c.8069G>A p.R2690Q | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as rs761090361, COSV56953739; called by muse, mutect2, varscan2
- NKX3-2 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 107/522 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.006); catalogued as rs1165080654; called by muse, mutect2, varscan2
- NLRP1 | c.3499C>T p.P1167S | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52563696; called by muse, mutect2, varscan2
- NPAP1 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs368007060; called by muse, mutect2, varscan2
- NREP | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1192701096, COSV67401246; called by muse, mutect2, varscan2
- OR1N1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 69/369 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.878); catalogued as COSV100509707; called by muse, mutect2, varscan2
- OR1N2 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 78/389 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs747161550; called by muse, mutect2, varscan2
- OR2B6 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs1385858165, COSV55128956; called by muse, mutect2, varscan2
- OR2L3 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 78/486 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs267598495, COSV63454411, COSV63454586; called by muse, varscan2
- OR4A16 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as rs779276988, COSV59043042; called by muse, mutect2, varscan2
- OR4A8 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.214); catalogued as rs753029197; called by muse, mutect2, varscan2
- OR4C6 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 70/359 reads (19%) | catalogued as rs866822511; called by muse, mutect2, varscan2
- OR4K1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs779313242, COSV53458864; called by muse, mutect2, varscan2
- OR51B2 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60916252, COSV60918089; called by muse, mutect2
- OR51G1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs200001303; called by muse, mutect2, varscan2
- OR51I1 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 72/335 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs772513140, COSV66507109; called by muse, mutect2, varscan2
- OR51L1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58626067; called by muse, mutect2, varscan2
- OR51Q1 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 69/370 reads (19%) | catalogued as COSV56180965; called by muse, mutect2, varscan2
- OR52J3 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66746941; called by muse, mutect2, varscan2
- OR52M1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs61751908, COSV64173096; called by muse, mutect2, varscan2
- OR56A4 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 69/412 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs201766466, COSV58110453; called by muse, mutect2, varscan2
- OR5AK2 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 64/355 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV58804384; called by muse, mutect2, varscan2
- OR5D16 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV65722340; called by muse, mutect2, varscan2
- OR5P2 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs751172323, COSV61490283; called by muse, mutect2, varscan2
- OR5T2 | c.821G>A p.R274K | Missense Mutation (SNP) | VAF 82/451 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV57589950; called by muse, mutect2, varscan2
- OR6K6 | c.511C>T p.Q171* (on ENST00000368144; = p.Q147* on NM_001005184.1) | Nonsense Mutation (SNP) | VAF 160/480 reads (33%) | catalogued as rs867534326, COSV100933680, COSV63744206; called by muse, mutect2, varscan2
- OR7E24 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV101509680; called by muse, mutect2, varscan2
- OR8H1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 79/436 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as rs199982658, COSV57293040; called by muse, mutect2, varscan2
- OTOGL | c.3169G>A p.D1057N (on ENST00000547103; = p.D1048N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72006002; called by muse, mutect2, varscan2
- OXGR1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV100037125; called by muse, mutect2, varscan2
- PADI3 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 67/371 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1218751799; called by muse, mutect2, varscan2
- PAPPA2 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 136/456 reads (30%) | catalogued as COSV62772983, COSV62783519; called by muse, mutect2, varscan2
- PAPPA2 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 126/394 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs376402363, COSV62795460; called by muse, mutect2, varscan2
- PCDH15 | c.3332C>T p.S1111F | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57269542, COSV57272409; called by muse, mutect2, varscan2
- PCDHB10 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 56/300 reads (19%) | catalogued as rs782513627, COSV53378155, COSV53382241; called by muse, mutect2, varscan2
- PCDHB12 | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV53397297; called by muse, mutect2, varscan2
- PCDHGA12 | c.2005C>G p.P669A | Missense Mutation (SNP) | VAF 112/555 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV99340906; called by muse, mutect2, varscan2
- PDZRN4 | c.1987G>A p.E663K (on ENST00000402685 / NM_001164595.2; = p.E405K on NM_013377.4) | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV54193916, COSV54215210; called by muse, mutect2, varscan2
- PGAP4 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329607289; called by muse, mutect2, varscan2
- PHOSPHO2 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55866779; called by muse, mutect2, varscan2
- PIEZO2 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1278747199, COSV57448440; called by muse, mutect2, varscan2
- PIK3C2B | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 138/449 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs992800920, COSV65810569; called by muse, mutect2, varscan2
- PIK3C2G | c.2791G>A p.D931N (on ENST00000676171; = p.D890N on NM_004570.5) | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as rs181773550; called by muse, mutect2, varscan2
- PIKFYVE | c.3703G>A p.A1235T | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.15); catalogued as rs1298916950; called by muse, mutect2, varscan2
- PIM2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 79/339 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs782025967; called by muse, mutect2, varscan2
- PKHD1L1 | c.9065C>T p.P3022L | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs1204171745; called by muse, mutect2, varscan2
- PLCB4 | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV53806752; called by muse, mutect2, varscan2
- PLCE1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV53361812; called by muse, mutect2, varscan2
- PLCE1 | c.5210C>T p.S1737F | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs762135003, COSV53337271; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLCZ1 | c.643C>T p.H215Y | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856355; called by muse, mutect2, varscan2
- PLXNB3 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 104/458 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs781907647, COSV62796565; called by muse, mutect2, varscan2
- PML | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 93/431 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV51446252; called by muse, mutect2, varscan2
- PNMA5 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 93/390 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as COSV100721571; called by muse, mutect2, varscan2
- POLR2C | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 58/435 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs746418763; called by muse, mutect2, varscan2
- POLRMT | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 107/535 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs758721890; called by muse, mutect2, varscan2
- PPP1R3F | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 138/476 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs781965989; called by muse, mutect2, varscan2
- PRAMEF19 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV101069261; called by muse, mutect2
- PRH1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 73/524 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.136); catalogued as rs868336454; called by muse, mutect2, varscan2
- PROKR1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 83/425 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58138799; called by muse, mutect2, varscan2
- PRX | c.4153G>A p.A1385T | Missense Mutation (SNP) | VAF 88/516 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99396447; called by muse, varscan2
- PTPRQ | c.3905G>A p.W1302* (on ENST00000616559; = p.W1260* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 66/314 reads (21%) | catalogued as rs1328431150, COSV57053776; called by muse, mutect2, varscan2
- PTPRT | c.4042C>T p.P1348S | Missense Mutation (SNP) | VAF 76/412 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.065); catalogued as rs539998222, COSV61971201; called by muse, mutect2, varscan2
- RAB9B | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs761856500, COSV54587178; called by muse, mutect2, varscan2
- RAD9B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1439336615, COSV63778564; called by muse, mutect2, varscan2
- RASEF | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 65/281 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1024096037, COSV64587684; called by muse, mutect2, varscan2
- RBM46 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs1340702800, COSV55980222; called by muse, mutect2, varscan2
- RECQL5 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 79/397 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53127496; called by muse, mutect2, varscan2
- REEP1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 126/567 reads (22%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.968); catalogued as rs896864468; called by muse, mutect2, varscan2
- RELN | c.5689G>A p.E1897K | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs757769185, COSV59034634; called by muse, mutect2, varscan2
- RGPD2 | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 30/221 reads (14%) | catalogued as rs750106821, COSV100553098; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RIPK3 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 71/381 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as rs748933892; called by muse, mutect2, varscan2
- RNF152 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 71/449 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs868149770, COSV57185533; called by muse, mutect2, varscan2
- ROGDI | c.339C>T p.I113= | Splice Region (SNP) | VAF 32/219 reads (15%) | catalogued as rs1161829085; called by muse, mutect2, varscan2
- ROS1 | c.5942C>T p.T1981I | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs994343717; called by muse, mutect2, varscan2
- RP1 | c.4133C>T p.P1378L | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV55122279; called by muse, mutect2, varscan2
- RRP7A | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 64/520 reads (12%) | catalogued as rs1343010242, COSV59899376; called by muse, mutect2, varscan2
- RTN4R | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 101/505 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1169647613; called by muse, mutect2, varscan2
- RUNDC3B | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV56693132; called by muse, mutect2, varscan2
- RUNDC3B | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs141715105; called by muse, mutect2, varscan2
- RXRG | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 64/424 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100717788; called by muse, mutect2, varscan2
- RXRG | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 128/447 reads (29%) | catalogued as rs1469851984, COSV100717262, COSV63232347; called by muse, mutect2, varscan2
- SAMD14 | c.823G>A p.E275K (on ENST00000330175 / NM_001257359.2; = p.E303K on NM_174920.4) | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs748701086; called by muse, mutect2, varscan2
- SAMSN1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 74/400 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs764770832; called by muse, mutect2, varscan2
- SBF1 | c.1295G>C p.R432P | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62369715; called by muse, mutect2, varscan2
- SCEL | c.1874G>A p.R625Q (on ENST00000349847 / NM_144777.3; = p.R605Q on NM_003843.4) | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1325547406, COSV62993478; called by muse, mutect2, varscan2
- SCN11A | c.3802G>A p.D1268N | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868738852, COSV56569036; called by muse, mutect2, varscan2
- SCN5A | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 82/453 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs779691420; called by muse, mutect2, varscan2
- SCYL2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); catalogued as rs756262769, COSV62569880; called by muse, mutect2, varscan2
- SDR16C5 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV58128335; called by muse, mutect2, varscan2
- SELENOP | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 78/431 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs1286049173; called by muse, mutect2, varscan2
- SERPINI1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as rs1360805408, COSV55508418; called by muse, mutect2, varscan2
- SF3B3 | c.3235C>T p.R1079C | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100210129; called by muse, mutect2, varscan2
- SIGLEC6 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV58432985; called by muse, mutect2, varscan2
- SIGLEC6 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 71/423 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1032239125, COSV58433515; called by muse, mutect2, varscan2
- SLC10A1 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 72/367 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs201366799; called by muse, mutect2, varscan2
- SLC16A7 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 77/361 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143688916; called by muse, mutect2, varscan2
- SLC1A7 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65195542; called by muse, mutect2, varscan2
- SLC25A21 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100490703; called by muse, mutect2, varscan2
- SLC38A1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.147); catalogued as rs267603474, COSV67065149; called by muse, mutect2, varscan2
- SLC4A10 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 72/372 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as rs1192069505; called by muse, mutect2, varscan2
- SLC5A12 | c.1820G>A p.S607N | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs778484568, COSV68448447; called by muse, mutect2, varscan2
- SLC6A16 | c.1745C>T p.T582I | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1386738788; called by muse, mutect2, varscan2
- SLC6A2 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.202); catalogued as rs781023132, COSV54922742; called by muse, mutect2, varscan2
- SLC7A2 | c.365C>T p.S122L (on ENST00000494857 / NM_001370338.1; = p.S162L on NM_003046.6) | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777770011, COSV50260346, COSV99135105; called by muse, mutect2, varscan2
- SLC9C1 | c.3124G>A p.D1042N | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); catalogued as rs1027275669, COSV59884347; called by muse, mutect2, varscan2
- SLCO1A2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs761378365, COSV100262296; called by muse, mutect2, varscan2
- SLCO1A2 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV56610669; called by muse, mutect2, varscan2
- SLCO5A1 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 96/468 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as rs1299419155; called by muse, mutect2, varscan2
- SLCO6A1 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 80/397 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as rs1222174664; called by muse, mutect2, varscan2
- SLITRK1 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 89/410 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV101000024; called by muse, mutect2, varscan2
- SMAP1 | c.902C>T p.S301F (on ENST00000370455 / NM_001044305.3; = p.S274F on NM_021940.5) | Missense Mutation (SNP) | VAF 64/379 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57636044; called by muse, mutect2, varscan2
- SMC3 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1167350115; called by muse, mutect2, varscan2
- SMCR8 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 81/353 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs768666900; called by muse, mutect2, varscan2
- SMIM18 | c.73T>C p.Y25H | Missense Mutation (SNP) | VAF 55/387 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1343284300; called by muse, mutect2, varscan2
- SMYD1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 83/422 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs1350355604; called by muse, mutect2, varscan2
- SNX10 | c.329T>A p.L110H | Missense Mutation (SNP) | VAF 68/281 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58400317; called by muse, mutect2, varscan2
- SPAG16 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs952107294, COSV100535196; called by muse, mutect2
- SPATA3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as rs535759916; called by muse, mutect2, varscan2
- SPTA1 | c.5781T>A p.D1927E | Missense Mutation (SNP) | VAF 130/375 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV63752671; called by muse, mutect2, varscan2
- SRPX | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs780388967, COSV100656068; called by muse, mutect2, varscan2
- SRRM2 | c.6415C>T p.L2139F | Missense Mutation (SNP) | VAF 64/377 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs775694559; called by muse, mutect2, varscan2
- STAB2 | c.2353G>A p.G785R | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140525330, COSV101186306; called by muse, mutect2, varscan2
- STK26 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as rs1025837586, COSV53748311; called by muse, mutect2, varscan2
- STX17 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs1388829406; called by muse, mutect2, varscan2
- SUCNR1 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 63/335 reads (19%) | catalogued as COSV62911813; called by muse, mutect2, varscan2
- SULF1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 71/356 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs748661181, COSV52676386, COSV99036127; called by muse, mutect2, varscan2
- SULF1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs762343638, COSV52676968; called by muse, mutect2, varscan2
- SULT2A1 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 65/361 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs770501427; called by muse, mutect2, varscan2
- SULT4A1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99970703, COSV99970729; called by muse, mutect2, varscan2
- SYNJ1 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV59157230; called by muse, mutect2, varscan2
- TACR1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV59482466; called by muse, mutect2, varscan2
- TAS2R39 | c.456G>A p.W152* | Nonsense Mutation (SNP) | VAF 70/401 reads (17%) | catalogued as rs867540296, COSV101489409; called by muse, mutect2, varscan2
- TBRG4 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 63/396 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.175); catalogued as rs146322161, COSV99345218; called by muse, mutect2, varscan2
- TBX3 | c.1354G>A p.E452K (on ENST00000257566 / NM_016569.4; = p.E432K on NM_005996.4) | Missense Mutation (SNP) | VAF 125/568 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1215745344, COSV57469277; called by muse, mutect2, varscan2
- TDG | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.123); catalogued as rs765206590, COSV57167720; called by muse, mutect2
- TDRD6 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 95/514 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs781647844, COSV60175543; called by muse, mutect2, varscan2
- TEKT4 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as rs782753394, COSV99726133; called by muse, mutect2, varscan2
- TERT | c.3284C>T p.S1095L | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV57205142; called by muse, mutect2, varscan2
- THRB | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 81/407 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs368681026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THSD4 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs777553782, COSV55986344; called by muse, mutect2, varscan2
- TLL1 | c.466A>T p.I156L | Missense Mutation (SNP) | VAF 81/349 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs1464881535; called by muse, mutect2, varscan2
- TLR4 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 55/331 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV62922407; called by muse, mutect2, varscan2
- TLR4 | c.1447T>G p.F483V (on ENST00000355622 / NM_138554.5; = p.F443V on NM_003266.4) | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100842688; called by muse, mutect2, varscan2
- TMEM39A | c.121A>G p.S41G | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV59901636; called by muse, mutect2, varscan2
- TNNI3K | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV53950159, COSV53950170; called by muse, mutect2, varscan2
- TOPORS | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1280716906; called by muse, mutect2, varscan2
- TOX3 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 95/471 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs202068223; called by muse, mutect2, varscan2
- TPH1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1403753212; called by muse, mutect2, varscan2
- TRAPPC12 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 124/572 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV60846914; called by muse, mutect2, varscan2
- TRAV8-3 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 81/308 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs1238063483; called by muse, mutect2, varscan2
- TRIM51 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 64/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55265158; called by muse, mutect2, varscan2
- TRIM51 | c.1136T>A p.L379H | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99793183; called by muse, mutect2
- TRMT10A | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 83/349 reads (24%) | catalogued as rs1314619609, CM1511765, COSV56744795, COSV99910855; called by muse, mutect2, varscan2
- TSBP1 | c.1584G>C p.K528N (on ENST00000617061; = p.K533N on NM_006781.5) | Missense Mutation (SNP) | VAF 102/567 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100898801; called by muse, mutect2
- TSPAN32 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1055595543, COSV51718906; called by muse, mutect2, varscan2
- TSSK3 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 91/427 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs770319759, COSV100344936, COSV61982706; called by muse, mutect2, varscan2
- TTC6 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.074); catalogued as COSV73287629; called by muse, mutect2, varscan2
- TTN | c.77710G>A p.A25904T (on ENST00000591111; = p.A18480T on NM_003319.4) | Missense Mutation (SNP) | VAF 77/394 reads (20%) | PolyPhen benign (0.079); catalogued as rs770320388; called by muse, mutect2, varscan2
- TTN | c.56078G>A p.G18693E (on ENST00000591111; = p.G11269E on NM_003319.4) | Missense Mutation (SNP) | VAF 49/282 reads (17%) | PolyPhen probably damaging (1); catalogued as rs779468027; called by muse, mutect2, varscan2
- TTN | c.22567G>A p.E7523K (on ENST00000591111; = p.E6596K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/384 reads (19%) | PolyPhen benign (0.007); catalogued as COSV59928823, COSV59985097; called by muse, mutect2, varscan2
- TTN | c.21749G>A p.G7250E (on ENST00000591111; = p.G6323E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/476 reads (21%) | PolyPhen benign (0.011); catalogued as rs764311341, COSV59977029; called by muse, mutect2, varscan2
- TTN | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 71/319 reads (22%) | PolyPhen benign (0.368); catalogued as rs727503709, COSV59864219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBXN7 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV56357048, COSV99580717; called by muse, mutect2, varscan2
- UGT1A10 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 78/382 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV60830843; called by muse, mutect2, varscan2
- UGT2B4 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776602181, COSV59318569; called by muse, mutect2, varscan2
- UGT3A2 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV56928272, COSV56930932; called by muse, mutect2, varscan2
- UPF3B | c.895G>A p.E299K (on ENST00000276201 / NM_080632.3; = p.E286K on NM_023010.3) | Missense Mutation (SNP) | VAF 82/305 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as COSV52230535; called by muse, mutect2, varscan2
- USP29 | c.1814G>A p.R605K | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54145940; called by muse, mutect2, varscan2
- USP54 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60447321; called by muse, mutect2, varscan2
- VWA3B | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs1474787610; called by muse, mutect2, varscan2
- WDR44 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 75/346 reads (22%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.027); catalogued as rs763160154; called by muse, mutect2, varscan2
- WDR49 | c.2011C>T p.P671S (on ENST00000308378 / NM_001366158.1; = p.P1012S on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52987378; called by muse, mutect2, varscan2
- WDR49 | c.1536G>A p.W512* (on ENST00000308378 / NM_001366158.1; = p.W853* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 47/280 reads (17%) | catalogued as COSV57718116; called by muse, mutect2, varscan2
- WTIP | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 74/489 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.733); catalogued as rs1230026447; called by muse, mutect2, varscan2
- XDH | c.3592G>A p.G1198R | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1413188904; called by muse, mutect2, varscan2
- XIRP1 | c.3176G>A p.R1059Q | Missense Mutation (SNP) | VAF 101/543 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs142701163, COSV100453738; called by muse, mutect2, varscan2
- ZAN | c.7546G>A p.E2516K | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.558); catalogued as rs774771582; called by muse, mutect2, varscan2
- ZBED9 | c.2313G>A p.M771I | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV71729209; called by muse, mutect2, varscan2
- ZBTB16 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 102/382 reads (27%) | catalogued as rs925443770, COSV60097785; called by muse, mutect2, varscan2
- ZFAND4 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 81/387 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs778398681; called by muse, mutect2, varscan2
- ZNF275 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.695); catalogued as rs782529078, COSV100936506; called by muse, mutect2, varscan2
- ZNF484 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs541159910, COSV100214595; called by muse, mutect2, varscan2
- ZNF541 | c.3273G>A p.M1091I | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV54546492; called by muse, mutect2, varscan2
- ZNF546 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 76/391 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.589); catalogued as rs199775611, COSV61259687; called by muse, mutect2, varscan2
- ZNF583 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 82/411 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52400822; called by muse, mutect2, varscan2
- ZNF609 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 112/483 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV58586508; called by muse, mutect2, varscan2
- ZNF831 | c.3367G>A p.D1123N | Missense Mutation (SNP) | VAF 173/554 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs374820470; called by muse, mutect2, varscan2
- ZNF880 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 71/440 reads (16%) | catalogued as rs201241467; called by muse, mutect2, varscan2
- A2M | c.389T>C p.F130S | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- AADACL4 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 85/447 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AATK | c.1357T>C p.F453L (on ENST00000326724 / NM_001080395.3; = p.F350L on NM_004920.2) | Missense Mutation (SNP) | VAF 130/502 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ABCA10 | c.1721A>T p.K574I | Missense Mutation (SNP) | VAF 75/346 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ABI2 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- AC126283.2 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 87/384 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACAN | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 86/512 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSBG2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ACSM3 | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 129/386 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN4 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAM2 | c.2041C>T p.H681Y | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM28 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 57/297 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ADAM30 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 100/410 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGB | c.4831G>A p.E1611K | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2
- AFAP1L2 | c.2272G>C p.V758L | Missense Mutation (SNP) | VAF 65/310 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- AFF2 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 122/428 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- AFP | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- AFP | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGXT | c.746A>G p.N249S | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- AKAP1 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 48/405 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- AKR1C3 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ALKBH1 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- AMIGO2 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 63/390 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ANGPTL4 | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 65/324 reads (20%) | called by muse, mutect2, varscan2
- ANGPTL6 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 85/418 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK3 | c.7793A>T p.K2598I | Missense Mutation (SNP) | VAF 76/383 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); called by muse, varscan2
- ANKK1 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ANKRD18B | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ANKRD30B | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ANKRD30BL | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AP4E1 | c.950T>A p.L317* | Nonsense Mutation (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- APCDD1L | c.1403A>G p.H468R | Missense Mutation (SNP) | VAF 162/547 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AREG | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARHGEF12 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ARMCX1 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARMCX1 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 65/329 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASAP1 | c.3306G>T p.Q1102H | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASTL | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ASXL1 | c.2759C>T p.P920L | Missense Mutation (SNP) | VAF 85/411 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ASXL1 | c.4036T>G p.S1346A | Missense Mutation (SNP) | VAF 94/439 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- ATF6B | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ATF7IP | c.3223C>T p.P1075S | Missense Mutation (SNP) | VAF 51/366 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ATF7IP | c.3224C>T p.P1075L | Missense Mutation (SNP) | VAF 50/363 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ATP10D | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATP6AP2 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 59/328 reads (18%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- B3GAT2 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 99/467 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- BAZ2A | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- BEND7 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 86/379 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BIRC6 | c.11986C>T p.P3996S | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- BRWD1 | c.5237C>T p.S1746L | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BTN1A1 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 97/285 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTN2A2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- C9orf153 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); called by muse, varscan2
- CACNA1F | c.2066C>T p.T689I | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CACNA2D3 | c.2624G>A p.G875E | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CACNG2 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CADM3 | c.163C>T p.H55Y (on ENST00000368125 / NM_001127173.3; = p.H89Y on NM_021189.5) | Missense Mutation (SNP) | VAF 93/466 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CASS4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CASS4 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CBY2 | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 67/370 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CCDC144A | c.3460T>A p.L1154I | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCDC168 | c.10481G>A p.G3494E | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CCDC175 | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CCDC70 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CCDC96 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 96/540 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, varscan2
- CDC42BPG | c.1595G>A p.R532K | Missense Mutation (SNP) | VAF 117/506 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC7 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH10 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDSN | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 208/630 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CFAP43 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CFAP65 | c.5158G>A p.D1720N | Missense Mutation (SNP) | VAF 71/389 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP92 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CFAP97 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 74/474 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2
- CHRNA7 | c.1192G>C p.V398L | Missense Mutation (SNP) | VAF 86/926 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2
- CHRNA7 | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 85/908 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CLEC2B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLHC1 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLPS | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 44/611 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CLSTN1 | c.1661T>C p.V554A (on ENST00000377298 / NM_001009566.3; = p.V544A on NM_014944.4) | Missense Mutation (SNP) | VAF 66/384 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNBD1 | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNGA2 | c.196T>A p.F66I | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNRIP1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- COL16A1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 69/397 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- COL1A2 | c.3880G>A p.G1294S | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A1 | c.3025G>A p.G1009S | Missense Mutation (SNP) | VAF 76/377 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL5A2 | c.3763C>T p.Q1255* | Nonsense Mutation (SNP) | VAF 59/363 reads (16%) | called by muse, mutect2, varscan2
- COL5A3 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 73/346 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- COL6A6 | c.4574G>A p.G1525D | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL8A1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 101/475 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CPXM2 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 67/366 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CSMD1 | c.2035C>T p.H679Y (on ENST00000520002; = p.H678Y on NM_033225.6) | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CTPS2 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CWH43 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CXorf21 | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 95/407 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CXorf66 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CYP2A6 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP3A5 | c.70C>T p.L24= | Splice Region (SNP) | VAF 34/238 reads (14%) | called by muse, mutect2, varscan2
- CYP4A22 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 46/459 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DAPP1 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCLK1 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCSTAMP | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDI1 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DDX47 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 39/233 reads (17%) | called by muse, mutect2, varscan2
- DDX60 | c.4586A>G p.N1529S | Missense Mutation (SNP) | VAF 57/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DECR1 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DENND1B | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 172/484 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMRTC1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- DNAH2 | c.4423C>T p.Q1475* | Nonsense Mutation (SNP) | VAF 65/373 reads (17%) | called by muse, mutect2, varscan2
- DNAH2 | c.12913G>A p.D4305N | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAI4 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DQX1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DSG1 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DUOX2 | c.1365C>A p.N455K | Missense Mutation (SNP) | VAF 62/389 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DUSP4 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 81/428 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYNC2H1 | c.12860C>T p.P4287L | Missense Mutation (SNP) | VAF 97/359 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ECE1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EDNRA | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EFL1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 103/402 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EHMT1 | c.3701C>A p.A1234D | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ELFN2 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 84/422 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELL2 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ELOVL2 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 107/353 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L2 | c.2861T>A p.I954N | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPPK1 | c.6824C>T p.P2275L | Missense Mutation (SNP) | VAF 26/583 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERAP1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 87/405 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EYS | c.5521G>A p.E1841K | Missense Mutation (SNP) | VAF 94/430 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- EYS | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- F8 | c.5734G>A p.E1912K | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- F8 | c.5470A>T p.N1824Y | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- FAM120C | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 99/362 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- FAM13C | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 80/451 reads (18%) | called by muse, mutect2, varscan2
- FAM237A | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAM53B | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 94/501 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- FAT2 | c.7643C>T p.S2548L | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- FAT3 | c.6603G>A p.M2201I | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO11 | c.1605C>G p.D535E (on ENST00000403359 / NM_001190274.2; = p.D451E on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.28); called by muse, mutect2
- FGF1 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- FKBP1C | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 105/442 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FLT4 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FMR1 | c.1763G>A p.R588K | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXR2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FSTL4 | c.202A>T p.K68* | Nonsense Mutation (SNP) | VAF 67/345 reads (19%) | called by muse, mutect2, varscan2
- GABRA2 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GABRE | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNTL5 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAR1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- GBP2 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GDPD1 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 25/307 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.158); called by muse, mutect2
- GHR | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GIPC2 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GJA9 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 75/380 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLIPR1L2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLYATL1 | c.574G>A p.E192K (on ENST00000317391 / NM_001354699.1; = p.E223K on NM_080661.4) | Missense Mutation (SNP) | VAF 100/357 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GOLGA6L9 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- GPD1 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR108 | c.1090G>A p.E364K (on ENST00000264080 / NM_001080452.1; = p.E122K on NM_020171.2) | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- GRIA2 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- GRIN2B | c.3527G>A p.R1176K | Missense Mutation (SNP) | VAF 72/410 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.113); called by muse, varscan2
- GRIN3A | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIN3B | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 102/529 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- HAUS6 | c.1831A>G p.I611V | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- HCN4 | c.1201T>G p.W401G | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HECTD3 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HIVEP2 | c.2021dup p.M675Hfs*19 | Frame Shift Ins (INS) | VAF 73/329 reads (22%) | called by mutect2, pindel, varscan2
- HSFX4 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPA13 | c.102_111del p.G35Lfs*18 | Frame Shift Del (DEL) | VAF 57/377 reads (15%) | called by mutect2, pindel, varscan2
- HSPA5 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 61/342 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HUWE1 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IDUA | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFI44L | c.505A>T p.K169* | Nonsense Mutation (SNP) | VAF 47/265 reads (18%) | called by muse, mutect2, varscan2
- IGHV3-53 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 49/448 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.588); called by muse, varscan2
- IL15RA | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 52/306 reads (17%) | called by muse, mutect2, varscan2
- ILVBL | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INO80 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 57/333 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- INPP5J | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 82/405 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INPP5J | c.1994A>G p.N665S (on ENST00000331075 / NM_001284285.2; = p.N297S on NM_001002837.2) | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- JAM3 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 30/159 reads (19%) | called by muse, mutect2, varscan2
- JUP | c.909G>A p.K303= | Splice Region (SNP) | VAF 48/223 reads (22%) | called by muse, mutect2, varscan2
- KAT6B | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNN2 | c.1496G>T p.R499M (on ENST00000264773; = p.R711M on NM_021614.4) | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- KCNQ1 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 65/368 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- KCNT2 | c.3205G>A p.G1069R | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- KCNV1 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 91/483 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- KDM6A | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 72/347 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KIAA1328 | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA2012 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 78/463 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- KIAA2012 | c.1474+1G>A p.X492_splice | Splice Site (SNP) | VAF 78/460 reads (17%) | called by muse, mutect2, varscan2
- KIF2B | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL11 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 89/401 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- KMT2A | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 70/313 reads (22%) | called by muse, mutect2, varscan2
- KMT2A | c.7637C>T p.S2546F | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- KMT2B | c.4842G>A p.W1614* | Nonsense Mutation (SNP) | VAF 77/410 reads (19%) | called by muse, mutect2, varscan2
- KRT4 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- KRT5 | c.562T>C p.F188L | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KSR2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 70/422 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LACTB | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LAMA1 | c.2510G>A p.G837E | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA3 | c.7687G>A p.E2563K (on ENST00000313654 / NM_198129.4; = p.E954K on NM_000227.6) | Missense Mutation (SNP) | VAF 57/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMC3 | c.4108C>T p.L1370F | Missense Mutation (SNP) | VAF 98/428 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- LDB3 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- LILRB1 | c.1123G>A p.G375R (on ENST00000427581; = p.G339R on NM_006669.6) | Missense Mutation (SNP) | VAF 68/516 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMAN2L | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 71/338 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMO7 | c.379C>T p.L127F (on ENST00000357063; = p.L142F on NM_005358.5) | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMOD2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 82/369 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0.007); called by muse, varscan2
- LOX | c.908A>T p.H303L | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LTBR | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 109/601 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LUZP2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by muse, mutect2
- MAFF | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 85/393 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MAGEA8 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 88/348 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- MAGEB6 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 93/466 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MAGEB6B | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MANSC4 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 64/375 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.062); called by muse, mutect2
- MAP3K21 | c.2419T>A p.F807I | Missense Mutation (SNP) | VAF 88/538 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- MARCOL | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 64/279 reads (23%) | called by muse, mutect2, varscan2
- MEPCE | c.1891-1G>A p.X631_splice | Splice Site (SNP) | VAF 56/209 reads (27%) | called by muse, mutect2, varscan2
- MGAM2 | c.3140C>T p.P1047L | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOG | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 98/543 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MPIG6B | c.501-1G>A p.X167_splice | Splice Site (SNP) | VAF 133/452 reads (29%) | called by muse, mutect2, varscan2
- MPO | c.1206G>A p.G402= | Splice Region (SNP) | VAF 48/243 reads (20%) | called by muse, mutect2, varscan2
- MPZL3 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- MROH2B | c.1517_1519delinsTA p.P506Lfs*10 | Frame Shift Del (DEL) | VAF 57/352 reads (16%) | called by pindel, varscan2*
- MS4A18 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MUC16 | c.34003C>T p.P11335S | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MUC16 | c.33262C>T p.P11088S | Missense Mutation (SNP) | VAF 44/365 reads (12%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MUC16 | c.32048G>A p.W10683* | Nonsense Mutation (SNP) | VAF 60/358 reads (17%) | called by muse, mutect2, varscan2
- MUC16 | c.24409G>A p.E8137K | Missense Mutation (SNP) | VAF 83/467 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- MUC4 | c.7337C>T p.A2446V | Missense Mutation (SNP) | VAF 117/1205 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.494); called by muse, mutect2
- MUC5B | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 99/497 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH15 | c.5105C>T p.S1702F | Missense Mutation (SNP) | VAF 86/441 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MYH9 | c.3260C>T p.A1087V | Missense Mutation (SNP) | VAF 69/309 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- MYL4 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MYMK | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 75/415 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- MYO10 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 84/457 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO15A | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 80/404 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYO15B | c.6215G>A p.G2072E | Missense Mutation (SNP) | VAF 94/502 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.267); called by muse, varscan2
- MYO18B | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 75/344 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- MYRF | c.1304G>A p.G435E (on ENST00000278836 / NM_001127392.3; = p.G426E on NM_013279.4) | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBAS | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 51/295 reads (17%) | called by muse, mutect2, varscan2
- NBEA | c.8807A>T p.N2936I | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- NCKAP5 | c.4847C>T p.T1616I | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- NCKAP5 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- NEXMIF | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 95/412 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- NLRP4 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NOTCH3 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 72/392 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.201); called by muse, varscan2
- NPVF | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 80/397 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NR1H2 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 115/541 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NRP2 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NTN5 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 83/468 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NXPE3 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 80/335 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- NYNRIN | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 83/456 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- NYX | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 129/429 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ODF1 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OGDHL | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 81/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OGFR | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); called by muse, varscan2
- OLFM4 | c.1391A>T p.E464V | Missense Mutation (SNP) | VAF 80/417 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPN1LW | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OPN4 | c.833A>T p.N278I | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OR10G4 | c.801G>A p.M267I | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR13C4 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- OR1F1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- OR1S2 | c.130T>A p.F44I | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- OR52E5 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 82/412 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- OR8J3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 72/404 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ORM1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- OVGP1 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 79/346 reads (23%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- P2RY2 | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 96/477 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); called by muse, mutect2
- PADI2 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAK2 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PALMD | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PAPPA | c.3584G>A p.G1195E | Missense Mutation (SNP) | VAF 51/347 reads (15%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PCARE | c.3041C>T p.S1014F | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PCBP2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH15 | c.4738G>A p.D1580N (on ENST00000644397 / NM_001354429.2; = p.D1522N on NM_001142771.2) | Missense Mutation (SNP) | VAF 49/358 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PCDH18 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 85/426 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PCDH18 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHA6 | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA8 | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCLO | c.8798C>T p.T2933I | Missense Mutation (SNP) | VAF 64/404 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE1C | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PDE9A | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PERCC1 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 87/431 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PHC1 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHKA1 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PIGN | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2G2A | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLD2 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 98/384 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PLOD1 | c.1510C>T p.H504Y | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- POMC | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 90/440 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POU3F4 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPDPFL | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 87/359 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PPP2R2B | c.400G>A p.D134N (on ENST00000394409; = p.D200N on NM_181674.2) | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PPP4R3C | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- PPP6C | c.793_795del p.C265del | In Frame Del (DEL) | VAF 59/335 reads (18%) | called by mutect2, pindel, varscan2
- PRDM8 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 98/504 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRG4 | c.622A>C p.T208P | Missense Mutation (SNP) | VAF 38/288 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); called by mutect2, varscan2
- PROSER3 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 70/449 reads (16%) | called by muse, mutect2, varscan2
- PRR14L | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 87/314 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PRX | c.2084A>G p.K695R | Missense Mutation (SNP) | VAF 83/403 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PSD2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 94/459 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTAFR | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN14 | c.3058C>T p.H1020Y | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PTPN22 | c.2359G>A p.G787S (on ENST00000359785 / NM_001193431.2; = p.G732S on NM_012411.5) | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRG | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PYGL | c.648G>A p.W216* | Nonsense Mutation (SNP) | VAF 43/248 reads (17%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- RAPH1 | c.1583C>T p.S528F (on ENST00000319170 / NM_213589.3; = p.S580F on NM_203365.4) | Missense Mutation (SNP) | VAF 61/299 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RBM23 | c.854C>T p.P285L (on ENST00000359890 / NM_001077351.2; = p.P269L on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RBPJ | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RELN | c.10234G>A p.G3412R | Missense Mutation (SNP) | VAF 84/355 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RGPD2 | c.4078G>A p.D1360N | Missense Mutation (SNP) | VAF 73/451 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RHPN2 | c.1892C>T p.T631I | Missense Mutation (SNP) | VAF 87/429 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- RNF44 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 97/434 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- RNFT2 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- RPGR | c.3047C>T p.S1016F (on ENST00000339363 / NM_001367249.1; = p.S811F on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- RSL1D1 | c.867A>C p.R289S | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RTN4RL2 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SACS | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SAMD7 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SATB1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SBK2 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 110/567 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCARB2 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCML2 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 81/355 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN1A | c.3209G>A p.G1070E (on ENST00000303395 / NM_001202435.3; = p.G1059E on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SCN2A | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SCN4A | c.2857C>T p.P953S | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC14L5 | c.216C>T p.I72= | Splice Region (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- SEC24B | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SENP7 | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SET | c.778G>A p.D260N (on ENST00000372692 / NM_001374326.1; = p.D247N on NM_003011.4) | Missense Mutation (SNP) | VAF 61/356 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- SF3A1 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 79/452 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SHANK2 | c.4112C>T p.P1371L | Missense Mutation (SNP) | VAF 73/340 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SIGLEC9 | c.423C>T p.A141= | Splice Region (SNP) | VAF 40/210 reads (19%) | called by muse, mutect2, varscan2
- SLC12A1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC22A16 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SLC5A8 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO2A1 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLFN14 | c.2226G>A p.M742I | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SLIT3 | c.4138G>A p.G1380R | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SMARCA5 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SORCS2 | c.3461A>C p.H1154P | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
540 further variants in this file (68 protein-altering or splice-affecting, 422 silent, 50 other) are not listed here.
